Somatic mutation profile of tumor specimen TCGA-C5-A3HF-01A (aliquot TCGA-C5-A3HF-01A-11D-A20U-09) from TCGA case TCGA-C5-A3HF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 25.0 years (9,115 days).
Specimen TCGA-C5-A3HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd5413cd-f500-49b3-a9be-13b1f66c32f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A3HF-10A (Blood Derived Normal), aliquot TCGA-C5-A3HF-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a40473-9f30-4650-a083-78041da5cfdd

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMCX2 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV100168078; called by muse, mutect2
- BCAT2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1455203509; called by muse, mutect2, varscan2
- CCDC92 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV99435826; called by muse, mutect2, varscan2
- CREB3L3 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1224772426, COSV50225622; called by muse, mutect2, varscan2
- ETFB | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as CM124681; called by muse, mutect2, varscan2
- GPC2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs756193927, COSV52786220; called by muse, mutect2, varscan2
- IGFALS | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1344866257; called by muse, mutect2, varscan2
- KIF1A | c.3926C>T p.S1309L (on ENST00000320389 / NM_001379639.1; = p.S1301L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs764487659, COSV100242815; called by muse, mutect2, varscan2
- KRTAP19-3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100477473; called by muse, mutect2
- MSH4 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99591275; called by muse, mutect2, varscan2
- MUC16 | c.24524C>T p.S8175L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV101198986; called by muse, mutect2, varscan2
- OR1C1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs767980381, COSV68715320; called by muse, mutect2, varscan2
- PTPRT | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1217327426, COSV61968991, COSV62017284; called by muse, mutect2, varscan2
- SF3A3 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV100885617; called by muse, mutect2
- SIX5 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as rs561325897; called by muse, mutect2, varscan2
- SMOX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as rs1240159183, COSV53862838; called by muse, mutect2, varscan2
- ZNF536 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs761469250, COSV62820342, COSV62821250; called by mutect2, varscan2
- AMY2B | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL8 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MINAR1 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MUC16 | c.29479C>T p.H9827Y | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- OAS3 | c.382del p.A128Pfs*6 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- OR13F1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPFIA1 | c.1490A>G p.K497R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SBF1 | c.3812A>G p.H1271R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- UROD | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XRRA1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASPM | c.6165A>G p.R2055= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- CUX2 | c.228G>A p.V76= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99919013; called by muse, mutect2, varscan2
- F2R | c.1137G>A p.Q379= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV100058380; called by muse, mutect2, varscan2
- INPP5K | c.247C>T p.L83= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100233649; called by muse, mutect2, varscan2
- LRRC30 | c.63G>A p.T21= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs774779431, COSV67301428; called by mutect2, varscan2
- RAB40A | c.126G>A p.P42= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs748229696, COSV58491236; called by muse, mutect2
- SETD5 | c.2907C>T p.L969= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs762853738, COSV100200345; called by muse, mutect2, varscan2
- SMC2 | c.2064G>A p.L688= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs777662020; called by muse, mutect2, varscan2
- SPEG | c.6393C>T p.F2131= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, varscan2
- SUPT20HL2 | c.843G>A p.L281= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TNNI3 | c.6G>A p.A2= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs397516361; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- UBN1 | c.684C>G p.L228= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1166542941, COSV52166879; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1278C>T p.L426= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99837516, COSV99837750; called by muse, mutect2, varscan2
- DEPDC5 | c.*957G>A | 3'UTR (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
